Gene-level copy-number profile of specimen HCM-CSHL-0322-C20-85A from HCMI case HCM-CSHL-0322-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: GB; Age at diagnosis: 69.1 years (25,229 days).
Specimen HCM-CSHL-0322-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 903b3da5-fa4e-4456-94d0-331f2fa8c6a7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0322-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/c54f2169-bfc5-49f1-8396-bb9ab3391678

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 12; copy number 2: 4,222; copy number 3: 30,059; copy number 4: 21,532; copy number 5: 2,180; copy number 6: 282; copy number 7: 80; copy number 8: 26; copy number 12: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,533,646–18,577,968, 1 gene: PI4KAP1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 109 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:27,172,259–29,505,947, 45 genes, copy number 7–8 (within-gene range 6–8): USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P, MTUS2, MTUS2-AS2.
- chr13:42,003,430–45,336,447, 61 genes, copy number 7 (broad region; genes not listed).
- chr22:18,615,581–18,615,900, 1 gene, copy number 13: Metazoa_SRP.
- chr22:18,773,665–18,843,399, 1 gene, copy number 12 (within-gene range 5–12): GGT3P.
- chr22:18,833,694–18,834,438, 1 gene, copy number 12: E2F6P1.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
